Somatic mutation profile of tumor specimen TCGA-A6-2679-01A (aliquot TCGA-A6-2679-01A-02D-1408-10) from TCGA case TCGA-A6-2679, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.4 years (26,820 days).
Specimen TCGA-A6-2679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3ab3b47-e56b-4662-b89d-5d597633b13c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2679-10A (Blood Derived Normal), aliquot TCGA-A6-2679-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d6da16b-9fca-400f-8d92-ea02e7a09f16

The open-access MAF lists 166 somatic variants for this specimen: 123 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 39, Nonsense Mutation 8, Frame Shift Del 4, Splice Region 3, Splice Site 2, Frame Shift Ins 2, 3'UTR 1, RNA 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/110 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.594G>A p.P198= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as rs368308772; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- TP53 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1193832023; called by muse, mutect2, varscan2
- ADGRL2 | c.2582G>T p.C861F (on ENST00000370717 / NM_001366005.1; = p.C848F on NM_012302.4) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs369954151, COSV54689781; called by muse, mutect2, varscan2
- ANO7 | c.1050C>A p.L350= (on ENST00000274979; = p.L296= on NM_001370694.2) | Splice Region (SNP) | VAF 15/49 reads (31%) | catalogued as COSV51470848; called by muse, mutect2, varscan2
- B4GALNT1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs200510000; called by muse, mutect2, varscan2
- BRINP3 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV66527447; called by muse, mutect2, varscan2
- CACNA1A | c.1185G>T p.W395C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV64212685; called by muse, mutect2
- CACNG2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs768367873, COSV55633776; called by muse, mutect2, varscan2
- CD163L1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs143343430; called by muse, mutect2, varscan2
- CLEC3A | c.364G>A p.A122T (on ENST00000651443; = p.A113T on NM_005752.6) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs147323906; called by muse, mutect2, varscan2
- CLGN | c.1523C>A p.T508N | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV57774745; called by muse, mutect2, varscan2
- COL6A2 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs755782924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF4L2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755701425, COSV60476952, COSV60481637; called by muse, mutect2, varscan2
- DDX43 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772942518, COSV64836434; called by muse, mutect2, varscan2
- DIAPH3 | c.1216C>T p.R406C (on ENST00000400324 / NM_001042517.2; = p.R143C on NM_030932.3) | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs746371932; called by muse, mutect2
- DMD | c.6613A>C p.R2205= | Splice Region (SNP) | VAF 40/253 reads (16%) | catalogued as COSV58954327; called by muse, mutect2, varscan2
- DMD | c.6612G>C p.K2204N | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV58954341; called by muse, mutect2, varscan2
- DMD | c.1601A>T p.K534M | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs760874706, COSV55902032; called by muse, mutect2, varscan2
- DSCAM | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757906374, COSV68028777; called by muse, mutect2, varscan2
- DYNC1I1 | c.948A>T p.E316D | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs771966085; called by muse, mutect2, varscan2
- FASN | c.4409G>T p.R1470L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60761226; called by muse, mutect2, varscan2
- FSIP1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1423247606, COSV63227037; called by muse, mutect2, varscan2
- GALR1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55315950; called by muse, mutect2, varscan2
- GIMAP1 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56187247; called by muse, mutect2, varscan2
- GPR52 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV52284326; called by muse, mutect2
- GRM7 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1160650838; called by muse, mutect2, varscan2
- HGF | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768451705, COSV55947351, COSV55955898; called by muse, mutect2, varscan2
- HSPA12A | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs782338580, COSV100979699; called by muse, mutect2, varscan2
- INF2 | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs752180110, COSV53036617; called by muse, mutect2, varscan2
- IRAG1 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs368228015; called by muse, mutect2, varscan2
- KCNQ4 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs760822719; called by muse, mutect2, varscan2
- KCNS2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370705767; called by muse, mutect2, varscan2
- LDOC1 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV65159713; called by muse, mutect2, varscan2
- LRP1B | c.13013G>T p.G4338V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101257447; called by muse, mutect2, varscan2
- MAP3K14 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60924491; called by muse, mutect2, varscan2
- MFSD2A | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1345860547; called by muse, mutect2
- MLLT10 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1179221232, COSV57004712; called by muse, mutect2, varscan2
- MMP8 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV52634387; called by muse, mutect2, varscan2
- MUC16 | c.25817G>A p.R8606H | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs182118027, COSV67443664; called by muse, mutect2, varscan2
- NAV2 | c.6025G>A p.A2009T (on ENST00000396087 / NM_001244963.2; = p.A1950T on NM_145117.5) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs764645844; called by muse, mutect2, varscan2
- NDOR1 | c.1649G>A p.R550H (on ENST00000371521 / NM_001144026.3; = p.R534H on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs377338578; called by muse, mutect2, varscan2
- NLRP8 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs199762057, COSV52584125; called by muse, mutect2, varscan2
- NPY5R | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100642804; called by muse, mutect2, varscan2
- NUMA1 | c.3643C>T p.R1215W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1359906978; called by muse, mutect2, varscan2
- OR1A2 | c.95dup p.L32Ffs*21 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs748774437; called by mutect2, varscan2
- OR4C3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs745422123, COSV60590719; called by muse, mutect2, varscan2
- OR7A17 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1247360685, COSV59415267; called by muse, mutect2, varscan2
- ORAI1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1555324161, COSV57491392; called by muse, mutect2, varscan2
- PCDH15 | c.4871C>G p.P1624R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV57278109, COSV57285305; called by muse, mutect2, varscan2
- PCDHA5 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs782323770, COSV65356157; called by muse, mutect2, varscan2
- PSMB1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.113); catalogued as rs775486561, COSV51529912; called by muse, mutect2, varscan2
- RASAL3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs751182066; called by muse, mutect2, varscan2
- RASSF9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs943336682, COSV63434230; called by muse, mutect2, varscan2
- RPAP2 | c.407del p.C136Sfs*35 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as COSV72509667; called by mutect2, pindel, varscan2
- RYR3 | c.5939G>A p.R1980Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs751678825; called by muse, mutect2, varscan2
- SEMA5B | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs758170926, COSV52101511; called by muse, mutect2, varscan2
- SIGLEC10 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs376850541; called by muse, mutect2, varscan2
- SLFN5 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763681518, COSV55483575, COSV55484148; called by muse, mutect2, varscan2
- SNRNP200 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1236137716; called by muse, mutect2, varscan2
- SPATC1L | c.465G>C p.M155I (on ENST00000291672 / NM_001142854.2; = p.M1? on NM_032261.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52432848; called by muse, mutect2, varscan2
- STAC3 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1202021365, COSV60414156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.3851G>A p.R1284Q (on ENST00000367255 / NM_182961.4; = p.R1291Q on NM_033071.3) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs779032686, COSV55076686; called by muse, mutect2, varscan2
- TBXT | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99752381; called by muse, mutect2, varscan2
- TNFSF9 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1380993370, COSV99832386; called by muse, mutect2, varscan2
- TNS1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1379322696, COSV50690136; called by muse, mutect2, varscan2
- TRNT1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs757405730, COSV99214090; called by muse, mutect2, varscan2
- USH2A | c.4826A>C p.E1609A | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV100233422, COSV56368435; called by muse, mutect2, varscan2
- VCX2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs770184596; called by muse, varscan2
- WNT2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756788881, COSV55413932; called by muse, mutect2, varscan2
- XKR6 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs374654242; called by muse, mutect2, varscan2
- YTHDC2 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as rs1392934988, COSV50736486; called by muse, mutect2, varscan2
- ZC3H12B | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs755253273; called by muse, mutect2, varscan2
- ZFHX4 | c.2011G>C p.G671R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV50635755; called by mutect2, varscan2
- ZFR2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs751547243; called by muse, mutect2, varscan2
- ZMIZ1 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775764570; called by muse, mutect2, varscan2
- ZNF536 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100835233, COSV62833010; called by muse, mutect2, varscan2
- ZNF749 | c.2086C>T p.H696Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61948337; called by muse, mutect2, varscan2
- A2ML1 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- AANAT | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APC | c.4247dup p.I1417Hfs*6 | Frame Shift Ins (INS) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- ATG5 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- BNIPL | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); called by muse, mutect2
- BTBD10 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1S | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CASS4 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.38); called by muse, mutect2
- COL6A6 | c.1917C>A p.S639R | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CREB3L2 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CYP2C8 | c.473A>T p.K158I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- DAOA | c.115_116del p.N39Lfs*27 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.1005A>C p.K335N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- DMRTB1 | c.578-2A>T p.X193_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- DNM1 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ERBB4 | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- EZH2 | c.1745C>T p.P582L (on ENST00000460911 / NM_001203247.2; = p.P587L on NM_004456.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.4493C>G p.A1498G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAGE10 | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- GNG11 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- HMCN1 | c.15923G>C p.G5308A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IKZF1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.156); called by muse, varscan2
- IQCG | c.1236_1237del p.E412Dfs*8 | Frame Shift Del (DEL) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- KCNC4 | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MON2 | c.3803C>A p.P1268H | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MUC16 | c.10891C>A p.P3631T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NDUFB5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- NFX1 | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NMI | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51V1 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR8K1 | c.554G>C p.C185S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR8K1 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHGA7 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PPP6R2 | c.1346del p.K449Sfs*24 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- RSF1 | c.2535_2549del p.W845_T850delins* | Nonsense Mutation (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- SURF2 | c.511_517+29del p.X171_splice | Splice Site (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- SYNE2 | c.5555G>A p.S1852N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIP12 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- TRIP13 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF804B | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- ZNF808 | c.1132A>G p.K378E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- ZNF831 | c.432C>A p.Y144* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- ABCA13 | c.5748T>G p.T1916= | Silent (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- ABCC12 | c.1611G>A p.V537= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CDRT15 | c.333G>A p.E111= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- CTC1 | c.1263C>T p.L421= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs536218211; called by muse, mutect2
- DCTN1 | c.2346C>T p.L782= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1391095426, COSV100720847; called by muse, mutect2, varscan2
- DENR | c.588A>G p.V196= | Silent (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- ELN | c.399A>G p.G133= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- ESRRB | c.649C>T p.L217= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1249165860, COSV55068880; called by muse, mutect2, varscan2
- ESYT1 | c.2964G>A p.L988= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- ESYT3 | c.543G>A p.T181= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs376570171; called by muse, mutect2, varscan2
- FIGN | c.570C>T p.N190= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs200547675, COSV60763869; called by muse, mutect2, varscan2
- GRIA4 | c.2616C>T p.R872= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs764376184, COSV56901369; called by muse, mutect2, varscan2
- IL12B | c.738A>G p.L246= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs192540461, COSV51455458; ClinVar: uncertain significance; called by mutect2, varscan2
- IMPG1 | c.183C>T p.F61= | Silent (SNP) | VAF 80/261 reads (31%) | catalogued as rs764226204, COSV64055878, COSV64057850; called by muse, mutect2, varscan2
- LRRTM3 | c.372T>C p.F124= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- MCM3AP | c.4224G>A p.T1408= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs756649954; called by muse, mutect2, varscan2
- NRROS | c.588C>T p.I196= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV60744707; called by muse, mutect2, varscan2
- PAK5 | c.357C>T p.H119= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs767346680, COSV62029632; called by muse, mutect2, varscan2
- PCDHA1 | c.1899G>A p.T633= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV65373152; called by muse, mutect2
- PCDHA10 | c.711C>T p.N237= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs148775418; called by muse, mutect2, varscan2
- PHF8 | c.1956T>C p.D652= (on ENST00000357988 / NM_001184896.1; = p.D616= on NM_015107.3) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs782298593; called by muse, varscan2
- PINK1 | c.1644T>C p.C548= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- PJA1 | c.1707A>G p.A569= (on ENST00000361478 / NM_145119.4; = p.A381= on NM_022368.5) | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.2658C>T p.G886= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1475287376, COSV99692723; called by muse, mutect2, varscan2
- PLXDC1 | c.336C>T p.A112= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs761292417; called by muse, mutect2, varscan2
- PRDM16 | c.99C>T p.S33= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs754219394; called by muse, mutect2, varscan2
- PRPF38B | c.453C>T p.H151= | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- PTCH1 | c.1230T>C p.S410= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59494387; called by muse, varscan2
- RAD54L2 | c.3006C>T p.P1002= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs145871194, COSV99621080, COSV99621712; called by muse, mutect2, varscan2
- RIMS1 | c.864C>T p.S288= | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- SCNN1G | c.390C>T p.G130= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- SRRM4 | c.585G>A p.S195= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs769309951, COSV57430869; called by muse, mutect2, varscan2
- STIL | c.2517A>T p.P839= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- TRIM49 | c.631C>A p.R211= | Silent (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- TSHZ3 | c.3204G>A p.P1068= | Silent (SNP) | VAF 68/182 reads (37%) | catalogued as rs1021335370, COSV53663401; called by muse, mutect2, varscan2
- ZCCHC9 | c.759G>A p.L253= | Silent (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- ZNF528 | c.1635A>G p.G545= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- ZNF648 | c.1527C>T p.C509= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV60570632; called by muse, mutect2, varscan2
- ZZEF1 | c.4323C>T p.C1441= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs145808707; called by muse, mutect2, varscan2
- ATP2B2 | c.*233G>A | 3'UTR (SNP) | VAF 18/99 reads (18%) | catalogued as rs377714027; called by muse, mutect2, varscan2
- DCHS2 | n.3576G>A | RNA (SNP) | VAF 12/118 reads (10%) | catalogued as rs868582579, COSV59730721; called by muse, mutect2
- ELMOD1 | c.-86+566A>C | Intron (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71641001 G>T | 3'Flank (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
